Somatic mutation profile of tumor specimen TCGA-FS-A1ZE-06A (aliquot TCGA-FS-A1ZE-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 41.7 years (15,249 days).
Specimen TCGA-FS-A1ZE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10d97d8d-dbab-42dd-a3db-6f70a745df1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZE-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZE-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c21bbd8-ea23-48d3-b75f-19ba66169dc7

The open-access MAF lists 170 somatic variants for this specimen: 115 protein-altering or splice-affecting, 51 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 51, Frame Shift Del 4, Splice Region 3, Nonsense Mutation 2, Splice Site 2, RNA 2, In Frame Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 74/165 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADGRL3 | c.1817G>A p.G606E (on ENST00000506720 / NM_001322402.2; = p.G538E on NM_015236.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV72231465; called by muse, mutect2, varscan2
- ADH1B | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.572); catalogued as COSV59295201; called by muse, mutect2, varscan2
- ALG10 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs753237274, COSV56793456, COSV56793665; called by muse, mutect2, varscan2
- AMBP | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54325017; called by muse, mutect2, varscan2
- AREL1 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 22/26 reads (85%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1026327750, COSV62666453; called by muse, mutect2, varscan2
- ARMC4 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV53467358; called by muse, mutect2, varscan2
- ATPSCKMT | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 35/60 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as COSV54727433; called by muse, mutect2, varscan2
- BIRC6 | c.8669G>A p.R2890Q | Missense Mutation (SNP) | VAF 94/231 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.375); catalogued as rs1423921189, COSV70195753, COSV70198632; called by muse, mutect2, varscan2
- BMP5 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.271); catalogued as COSV63702003; called by muse, mutect2, varscan2
- C5AR1 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs141160351; called by muse, mutect2, varscan2
- CACNA1G | c.5229G>A p.V1743= | Splice Region (SNP) | VAF 21/44 reads (48%) | catalogued as rs532438743, COSV61734048; called by muse, mutect2, varscan2
- CADM2 | c.928G>A p.V310I (on ENST00000407528 / NM_001167674.2; = p.V312I on NM_153184.4) | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.047); catalogued as COSV67393580; called by muse, mutect2, varscan2
- CCDC73 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs904230248, COSV58802407; called by muse, mutect2, varscan2
- CDK5RAP1 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59427191; called by muse, mutect2, varscan2
- CEP164 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 88/101 reads (87%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs566379982, COSV54044646; called by muse, mutect2, varscan2
- CLU | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as CM124610, COSV57066844; called by muse, mutect2, varscan2
- CMYA5 | c.5404G>A p.V1802I | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV71408370; called by muse, mutect2, varscan2
- CNTNAP5 | c.1472G>T p.G491V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70502012; called by muse, mutect2
- COL7A1 | c.6931G>A p.E2311K | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1283925267, COSV60400203; called by muse, mutect2, varscan2
- CRB2 | c.1295G>A p.G432E | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV63504695; called by muse, mutect2, varscan2
- CRISP2 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs200917120, COSV59254001, COSV59255565; called by muse, mutect2, varscan2
- CSMD1 | c.6020T>C p.L2007S (on ENST00000520002; = p.L2006S on NM_033225.6) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59359973; called by muse, mutect2, varscan2
- CSMD3 | c.9862+1G>A p.X3288_splice (on ENST00000297405 / NM_001363185.1; = p.X3119_splice on NM_052900.3) | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as rs758872376, COSV52268067; called by muse, mutect2, varscan2
- CYP2C19 | c.333A>G p.G111= | Splice Region (SNP) | VAF 40/76 reads (53%) | catalogued as COSV64908800; called by muse, mutect2
- CYP4F8 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV57854931; called by muse, mutect2, varscan2
- DAO | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99948380; called by muse, mutect2, varscan2
- DAW1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV59366543, COSV59367655; called by muse, mutect2, varscan2
- DLEC1 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV57304218; called by muse, mutect2
- DMGDH | c.219G>A p.M73I | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV54867057; called by muse, mutect2, varscan2
- DNAH5 | c.11665G>A p.E3889K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs1263116606, COSV54242803; called by muse, mutect2, varscan2
- DSN1 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.77); catalogued as COSV65519862; called by muse, mutect2, varscan2
- EFR3A | c.1890G>A p.M630I | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as COSV54460619; called by muse, mutect2, varscan2
- ELOA3C | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 64/2255 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as COSV55304720; called by muse, mutect2
- ETV5 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.93); catalogued as COSV60504990; called by muse, mutect2, varscan2
- FPR2 | c.929G>C p.R310P | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60674046; called by muse, mutect2, varscan2
- FSHB | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1159738542, COSV54222557; called by muse, mutect2, varscan2
- GALNT8 | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52900108; called by muse, mutect2, varscan2
- GFRAL | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV61233748; called by muse, mutect2, varscan2
- GIGYF1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs199620213; called by muse, varscan2
- GLRA3 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.392); catalogued as COSV56867173; called by muse, mutect2, varscan2
- GLRB | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52418823, COSV52419681; called by muse, mutect2, varscan2
- HHLA2 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as rs367817011, COSV63316232; called by muse, mutect2, varscan2
- JAKMIP1 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV51540748, COSV99290228; called by muse, mutect2, varscan2
- KHDC3L | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.873); catalogued as COSV64869592; called by muse, mutect2, varscan2
- KIAA1217 | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs757942178, COSV64610446; called by muse, mutect2, varscan2
- KLF6 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 134/271 reads (49%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV51495579; called by muse, mutect2, varscan2
- KLHL23 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 63/134 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as COSV55868788; called by muse, mutect2, varscan2
- KMT2C | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV99030496; called by muse, mutect2, varscan2
- KRTAP12-3 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV59973384; called by muse, mutect2, varscan2
- LPAR4 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 56/61 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1350858114, COSV70912427; called by muse, mutect2, varscan2
- LRIT1 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as rs753319936, COSV64511886; called by muse, mutect2, varscan2
- LRRC4C | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1323279700, COSV53423393; called by muse, mutect2, varscan2
- MAB21L3 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.192); catalogued as COSV65674329; called by muse, mutect2, varscan2
- MARCHF6 | c.2531T>A p.L844* | Nonsense Mutation (SNP) | VAF 53/82 reads (65%) | catalogued as COSV56884862; called by muse, mutect2, varscan2
- MAT2A | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52089696; called by muse, mutect2, varscan2
- MCF2L2 | c.2658G>A p.M886I | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1160815249, COSV61058826; called by muse, mutect2, varscan2
- MCM8 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as rs1480630563, COSV54517049; called by muse, mutect2, varscan2
- MECOM | c.2120C>T p.S707L (on ENST00000468789 / NM_001105078.4; = p.S895L on NM_004991.4) | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV52970771; called by muse, mutect2, varscan2
- MEMO1 | c.806C>T p.S269L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs775618103, COSV54451903; called by muse, mutect2, varscan2
- MMP15 | c.1884G>A p.M628I | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.439); catalogued as rs777349152, COSV54680905; called by muse, mutect2, varscan2
- MN1 | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 46/56 reads (82%) | catalogued as COSV56560768; called by muse, mutect2, varscan2
- NCKAP1L | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.425); catalogued as COSV53210461; called by muse, mutect2, varscan2
- NCKAP5L | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV60131468; called by muse, mutect2, varscan2
- NCOR2 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100656547, COSV62301834; called by muse, mutect2, varscan2
- NIBAN3 | c.665G>A p.G222D | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.993); catalogued as COSV56306189; called by muse, mutect2, varscan2
- NMBR | c.970C>T p.L324F | Missense Mutation (SNP) | VAF 54/96 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562388261, COSV57802667; called by muse, mutect2, varscan2
- OR4K14 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV59293382; called by muse, mutect2, varscan2
- OR5H6 | c.643G>A p.V215I (on ENST00000642105; = p.V199I on NM_001005479.2) | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.8); PolyPhen benign (0.1); catalogued as COSV67351908; called by muse, mutect2, varscan2
- OR7G1 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.133); catalogued as COSV53318488; called by muse, mutect2, varscan2
- ORM1 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV52280601; called by muse, mutect2, varscan2
- OSBPL10 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV67342621; called by muse, mutect2, varscan2
- PDLIM3 | c.149C>T p.P50L (on ENST00000284770 / NM_001257963.1; = p.P129L on NM_014476.6) | Missense Mutation (SNP) | VAF 45/49 reads (92%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as rs1418573250, COSV52980590, COSV52980632; called by muse, mutect2, varscan2
- PGD | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs771627468, COSV54622568; called by muse, mutect2, varscan2
- PKMYT1 | c.1421_1422del p.E474Afs*10 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | catalogued as rs780165019; called by pindel, varscan2
- PLBD1 | c.1265T>G p.L422R | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV53694317, COSV53695196; called by muse, mutect2, varscan2
- PPFIA4 | c.1121G>A p.R374K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV55319466; called by muse, mutect2, varscan2
- PROM2 | c.1053G>A p.E351= | Splice Region (SNP) | VAF 36/75 reads (48%) | catalogued as COSV100468739, COSV58299905; called by muse, mutect2, varscan2
- SACS | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as rs747773669, COSV66535662; called by muse, mutect2, varscan2
- SLC6A20 | c.1594G>A p.G532R | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.957); catalogued as COSV62072217; called by muse, mutect2, varscan2
- SP140 | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1474403336, COSV59453306; called by muse, mutect2, varscan2
- ST8SIA3 | c.110A>G p.N37S | Missense Mutation (SNP) | VAF 29/69 reads (42%) | PolyPhen benign (0); catalogued as COSV60654893; called by muse, mutect2, varscan2
- SUCO | c.1282A>G p.K428E | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55269273; called by muse, mutect2, varscan2
- SYNDIG1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 94/152 reads (62%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.06); catalogued as COSV65238012; called by muse, mutect2, varscan2
- TADA2B | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs1384502287, COSV53826772; called by muse, mutect2, varscan2
- TAT | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as rs868508459, COSV63532582; called by muse, mutect2, varscan2
- TECR | c.227T>A p.L76Q | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV53108794; called by muse, mutect2, varscan2
- THAP10 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.672); catalogued as rs1379908298, COSV51436959; called by muse, mutect2, varscan2
- TIAM2 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as rs1031872527, COSV59692110; called by muse, mutect2, varscan2
- TJP3 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.246); catalogued as rs1360570669, COSV53661667; called by muse, mutect2, varscan2
- TMPRSS13 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV70627222; called by muse, mutect2, varscan2
- TP63 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.885); catalogued as rs754361670, COSV53209193, COSV53218266; called by muse, mutect2, varscan2
- TRBV24-1 | c.34T>C p.Y12H | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs1177302872; called by muse, mutect2, varscan2
- TSN | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV67605425; called by muse, mutect2, varscan2
- TTN | c.35773G>A p.E11925K (on ENST00000591111; = p.E4501K on NM_003319.4) | Missense Mutation (SNP) | VAF 53/143 reads (37%) | PolyPhen probably damaging (0.987); catalogued as rs867892254, COSV60084165; called by muse, mutect2, varscan2
- UNC93A | c.499+1G>A p.X167_splice | Splice Site (SNP) | VAF 34/89 reads (38%) | catalogued as COSV57807252; called by muse, mutect2, varscan2
- UROC1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as rs1394563001, COSV52037102; called by muse, mutect2, varscan2
- VN1R5 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs1411105588; called by muse, mutect2, varscan2
- VRK2 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as COSV60879312; called by muse, mutect2, varscan2
- WAPL | c.3023C>T p.S1008L | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.334); catalogued as rs754307691, COSV53938426; called by muse, mutect2, varscan2
- WDR1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53332575; called by muse, mutect2, varscan2
- WNK1 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs575889688, COSV100265820, COSV60048839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZMYM3 | c.2052G>T p.Q684H | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58739798; called by muse, mutect2, varscan2
- ZNF43 | c.1205A>G p.E402G | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV61685195; called by muse, mutect2, varscan2
- ZNF43 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV61685199; called by muse, mutect2, varscan2
- ZNF581 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV99552993; called by muse, mutect2, varscan2
- ZNF701 | c.388G>A p.G130S (on ENST00000301093; = p.G64S on NM_018260.3) | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.455); catalogued as COSV56526422; called by muse, mutect2, varscan2
- ZNF714 | c.499C>T p.H167Y | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.878); catalogued as COSV52510515; called by muse, mutect2, varscan2
- ZSWIM2 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54577938; called by muse, mutect2, varscan2
- CUL5 | c.1505_1513dup p.V502_E504dup | In Frame Ins (INS) | VAF 20/30 reads (67%) | called by mutect2, varscan2
- HNF1B | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 218/474 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- IGHV3-74 | c.5A>G p.E2G | Missense Mutation (SNP) | VAF 54/70 reads (77%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IPO11 | c.629_632del p.R210Hfs*5 | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | called by pindel, varscan2
- NEB | c.8734del p.S2912Pfs*17 | Frame Shift Del (DEL) | VAF 29/104 reads (28%) | called by mutect2, pindel, varscan2
- NOL4 | c.1132del p.L378* | Frame Shift Del (DEL) | VAF 85/255 reads (33%) | called by mutect2, pindel, varscan2
- ABCB1 | c.3258C>T p.F1086= | Silent (SNP) | VAF 28/65 reads (43%) | catalogued as COSV55958996; called by muse, mutect2, varscan2
- ACAN | c.6604C>T p.L2202= | Silent (SNP) | VAF 44/87 reads (51%) | catalogued as COSV61366185; called by muse, mutect2, varscan2
- BBS7 | c.1726C>T p.L576= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV52658503; called by muse, mutect2, varscan2
- C5AR1 | c.522C>T p.Y174= | Silent (SNP) | VAF 67/162 reads (41%) | catalogued as COSV100753919; called by muse, mutect2, varscan2
- CCDC146 | c.1212G>A p.E404= | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs1161447511, COSV53552358; called by muse, mutect2, varscan2
- CCDC60 | c.1431G>A p.V477= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV59543297; called by muse, mutect2, varscan2
- CNBD2 | c.465C>T p.F155= | Silent (SNP) | VAF 164/207 reads (79%) | catalogued as rs776078829, COSV62586836; called by muse, mutect2, varscan2
- CNTNAP2 | c.3330A>G p.G1110= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV62155842, COSV62188099; called by muse, varscan2
- CPNE9 | c.402G>A p.G134= | Silent (SNP) | VAF 32/90 reads (36%) | catalogued as COSV56068476; called by muse, mutect2, varscan2
- DMRT3 | c.1293A>G p.E431= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV51907045; called by muse, mutect2, varscan2
- DNAH11 | c.4353G>A p.A1451= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs373969291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPYD | c.1719C>T p.T573= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV64609209; called by muse, mutect2, varscan2
- FCAR | c.733C>T p.L245= | Silent (SNP) | VAF 157/331 reads (47%) | catalogued as COSV62031176; called by muse, mutect2, varscan2
- GRIN3A | c.2691T>C p.H897= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as COSV62456761; called by muse, mutect2, varscan2
- HLA-DOA | c.288G>A p.L96= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV57715212; called by muse, mutect2, varscan2
- KMT2C | c.12408G>A p.L4136= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as COSV100064307; called by muse, mutect2, varscan2
- KRT13 | c.843C>T p.Y281= | Silent (SNP) | VAF 109/230 reads (47%) | catalogued as rs770647667, COSV55839553; called by muse, mutect2, varscan2
- LANCL2 | c.486T>C p.Y162= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV54651237; called by muse, mutect2, varscan2
- MARCHF1 | c.390C>T p.F130= (on ENST00000274056; = p.F113= on NM_017923.4) | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as rs1436299421, COSV56821826; called by muse, mutect2, varscan2
- MST1R | c.2847G>T p.G949= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV56572031; called by muse, mutect2, varscan2
- MYO16 | c.414C>T p.N138= | Silent (SNP) | VAF 58/92 reads (63%) | catalogued as COSV51809480; called by muse, mutect2, varscan2
- NPVF | c.396G>A p.G132= | Silent (SNP) | VAF 203/296 reads (69%) | catalogued as COSV56061332; called by muse, mutect2
- NWD1 | c.1581C>T p.L527= | Silent (SNP) | VAF 38/77 reads (49%) | catalogued as rs908298617, COSV60348186; called by muse, mutect2, varscan2
- ODF2 | c.1875C>T p.I625= (on ENST00000434106 / NM_153433.2; = p.I601= on NM_002540.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as rs199784940, COSV63546735; called by muse, mutect2, varscan2
- OR2T12 | c.465C>T p.L155= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as COSV58778887; called by muse, mutect2, varscan2
- OR8B12 | c.823C>T p.L275= | Silent (SNP) | VAF 37/38 reads (97%) | catalogued as COSV60912401; called by muse, mutect2, varscan2
- PCLO | c.8103G>A p.E2701= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs1419126781, COSV61655285; called by muse, mutect2, varscan2
- PCNA | c.216C>T p.L72= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as rs267605997, COSV64770696; called by muse, mutect2, varscan2
- PIK3R1 | c.807C>T p.S269= | Silent (SNP) | VAF 63/96 reads (66%) | catalogued as COSV57135774; called by muse, mutect2, varscan2
- PRKAR2B | c.51G>A p.T17= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs745684074, COSV55926605; called by muse, mutect2
- PRR5L | c.555G>A p.S185= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs375583647, COSV61122827; called by muse, mutect2, varscan2
- PYGM | c.945C>T p.S315= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV51223518; called by muse, mutect2, varscan2
- RALGAPB | c.1332G>A p.L444= | Silent (SNP) | VAF 108/168 reads (64%) | catalogued as COSV53441961; called by muse, mutect2, varscan2
- ROBO2 | c.123C>T p.I41= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1366732590, COSV59909419; called by muse, mutect2, varscan2
- RRP9 | c.486C>T p.F162= | Silent (SNP) | VAF 66/134 reads (49%) | catalogued as COSV51753847; called by muse, mutect2, varscan2
- SCNN1D | c.276C>T p.S92= (on ENST00000338555; = p.S256= on NM_001130413.4) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV57643555; called by muse, mutect2, varscan2
- SLC4A11 | c.168C>T p.F56= | Silent (SNP) | VAF 22/94 reads (23%) | catalogued as rs577502313, COSV66260244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPATA31D1 | c.4563G>A p.R1521= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1295811704, COSV61193403; called by muse, mutect2, varscan2
- SPDL1 | c.1368C>T p.L456= | Silent (SNP) | VAF 47/52 reads (90%) | catalogued as COSV54668910; called by muse, mutect2, varscan2
- ST13 | c.903A>C p.G301= | Silent (SNP) | VAF 211/221 reads (95%) | catalogued as COSV53422981; called by muse, mutect2, varscan2
- SUPT5H | c.1497C>T p.F499= | Silent (SNP) | VAF 83/178 reads (47%) | catalogued as rs1450937263, COSV63238484; called by muse, mutect2, varscan2
- TBC1D12 | c.1071G>A p.Q357= | Silent (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- TMEM26 | c.873G>A p.A291= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as rs199546375; called by muse, mutect2, varscan2
- TMEM63C | c.553C>T p.L185= | Silent (SNP) | VAF 38/48 reads (79%) | catalogued as rs774211840, COSV53606720; called by muse, mutect2, varscan2
- TPCN2 | c.327G>A p.A109= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs190040116; called by muse, mutect2, varscan2
- TSC22D4 | c.849C>T p.F283= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as rs199747034, COSV55724949; called by muse, mutect2, varscan2
- TTYH3 | c.141G>A p.G47= | Silent (SNP) | VAF 51/55 reads (93%) | catalogued as rs1031008606, COSV51862100; called by muse, mutect2, varscan2
- UQCC1 | c.711G>C p.R237= | Silent (SNP) | VAF 216/278 reads (78%) | catalogued as COSV62903182; called by muse, varscan2
- ZNF365 | c.987A>T p.V329= | Silent (SNP) | VAF 86/169 reads (51%) | catalogued as COSV101237926; called by muse, mutect2, varscan2
- ZNF581 | c.114C>T p.S38= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99552995, COSV99553272; called by muse, mutect2, varscan2
- ZSWIM3 | c.672C>T p.H224= | Silent (SNP) | VAF 45/228 reads (20%) | catalogued as COSV54850007; called by muse, mutect2, varscan2
- C12orf77 | n.467T>C | RNA (SNP) | VAF 24/58 reads (41%) | called by muse, mutect2, varscan2
- CLEC14A | c.*2G>A | 3'UTR (SNP) | VAF 44/89 reads (49%) | catalogued as COSV100643455; called by muse, mutect2, varscan2
- H3-3B | chr17:75784775 G>A | 5'Flank (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53145407; called by muse, mutect2, varscan2
- SLC22A20P | n.1383G>A | RNA (SNP) | VAF 8/21 reads (38%) | catalogued as rs754493452; called by muse, mutect2, varscan2
